Surgical pathology report (de-identified scan), TCGA case TCGA-IB-AAUU, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-AAUU-01A (Primary Tumor).

[page 1 of 3]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected

Time Reported

Order Number

Status

Final

Time Received

Time Transmitted

Ordering Provider

Relevant Information

Location

Copied To

Report Patient

Demographics (for
verification purposes)

Sex: M

ICD-O-3
Adenocarcinoma, duct NOS 8500/3
Site: Pancreas head c25.0
9/25/20/14

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number

Collected Date/Time

Received Date/Time

Pathologist

Specimen Description

A. Lymph node group 8 at

B. Gallbladder at

C. Bile duct margin at

D. Pancreas and duodenum at

Clinical Information

Distal bile duct ampullary tumor, pancreas cancer.

Infectious patient: No

Immunocompromised: No

History of neoplasm: No

Diagnosis

A. Lymph Node Group 8:

- One benign reactive lymph node.
- Negative for malignancy.

B. Gallbladder:

- Mild acute inflammation.
- Reactive cystic duct lymph node.
- Negative for malignancy.

C. Bile Duct Margin:

- Negative for malignancy or dysplasia.

D. Pancreas and Duodenum, Partial Pancreaticoduodenectomy:

- Invasive moderately to poorly differentiated ductal carcinoma of pancreas.
- Carcinoma involves pancreatic head, tissue around distal common bile duct, lower common bile duct mucosa (cancerization), and ampullary duodenal mucosa.
- Extensive PanIN.
- Lymphovascular invasion not identified.
- Extensive perineural invasion.
- One of fourteen peripancreatic lymph nodes positive for metastatic carcinoma (1/14).
- Resection margins free of tumor: 0.1 cm from the closest vessel bed margin, and 0.5 cm from pancreatic distal resection margin.
- See Synoptic Report.

Reported by:

Electronically signed by:

Verified:

[page 2 of 3]
Synoptic Report

SPECIMEN:

Head of pancreas

Duodenum

Stomach

Common bile duct

Gallbladder

PROCEDURE:

Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

TUMOR SITE:

Pancreatic head

TUMOR SIZE:

Greatest dimension: 3.0 cm

HISTOLOGIC TYPE:

Ductal adenocarcinoma

HISTOLOGIC GRADE:

G3: Poorly differentiated

MICROSCOPIC TUMOR EXTENSION:

Tumor invades ampulla of Vater or sphincter of Oddi

Tumor invades duodenal wall

Tumor invades peripancreatic soft tissues

MARGINS:

Margins uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 0.1 mm

Specified margin: Vessel bed margin

Margins uninvolved by carcinoma in situ

TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):

Not known

LYMPH-VASCULAR INVASION:

Not identified

PERINEURAL INVASION:

Present

PRIMARY TUMOR (pT):

pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery

REGIONAL LYMPH NODES (pN):

pN1: Regional lymph node metastasis

DISTANT METASTASIS (pM):

Not applicable

ADDITIONAL PATHOLOGIC FINDINGS:

Pancreatic intraepithelial neoplasia (highest grade: PanIN II and III)

Gross Description

Received are specimen containers A to D. All requisitions and specimen containers are labelled with the patient's name, . The cassettes and identifiers are labelled with the Surgical Number

A. Specimen is received fresh, subsequently placed in formalin. The container is designated as "A. Lymph node group 8". Specimen consists of a tan to dark brown portion of fibrofatty tissue measuring 2.3 x 1.0 x 0.4 cm. Specimen is bisected. Cut surface is tan, brown and variegated. Specimen is submitted in toto in one cassette.
B. Specimen is received fresh, subsequently placed in formalin. The container is designated as "B. Gallbladder". Specimen consists of an intact gallbladder measuring 7.7 x 2.7 x 1.5 cm. Serosal surface is smooth and grey-tan. The lumen contains thick green tan mucoid bile. The cystic duct is patent. Cystic duct lymph node is identified and measures 1.2 x 0.8 x 0.5 cm. The mucosa is tan and trabeculated. The wall averages 0.6 cm in thickness. Sections are submitted as follows:

- B1. cystic duct margin and cystic duct lymph node is bisected submitted in toto
- B2. representative sections from neck body and fundus
- B3. representative section from cystic duct.

C. Specimen is received fresh, subsequently placed in formalin. The container is designated as "C. Bile duct margin at ".
The specimen consists of circular fragment of tan tissue; 0.8 cm diameter. Submitted in toto for quick section.

D. Specimen is received fresh, subsequently placed in formalin. The container is designated as "D. Pancreas and duodenum at ". Specimen consists of a Whipple's of resection including distal stomach (4.5 cm in length x 5.0 cm in circumference), portion of pancreas (5.8 x 4.0 x 2.5 cm), segment of duodenum (27.5 cm in length x 5.3 cm in circumference), and attached peripancreatic soft tissue measuring 3.5 cm in maximum depth. Proximal margin of stomach and distal margin are stapled. Specimen is inked as follows: bile duct margin-blue, uncinate margin-orange, vessel bed margin-black. Stomach and duodenal serosal surfaces are gray-tan, smooth and dusky. Stomach mucosa is tan and grossly unremarkable. Duodenal mucosa is tan with a sharp demarcation to dark brown 9.5

[page 3 of 3]
cm from the proximal margin. Duodenal mucosa otherwise grossly appears unremarkable. The common bile duct measures 3.5 cm in length and averages 2.2 cm in circumference. The common bile duct mucosa is light tan and appears fibrous and abnormal. The abnormal mucosa involves the entire common bile duct and comes within 2.0 cm to the uncinate margin and 0.5 cm to the vessel bed margin. pancreatic parenchyma is yellow-tan and lobulated, and is slightly firm in the area underlying the common bile duct. This firm area measures 3.0 x 2.5 x 1.0 cm and comes within 0.3 cm to the vessel bed margin. Two possible lymph nodes are identified within the peripancreatic soft tissue both measuring 0.4 cm in maximum dimension. Sections are submitted as follows:

- D1. proximal margin shave section bisected
D2/3. distal margin shave section bisected
D4. common bile duct margin shave section
D5 to 9. common bile duct transitioning to ampulla and duodenum with underlying pancreas
D10. common bile duct in relation to uncinate and vessel bed margins
(please note common bile duct is separate from underlying tissue due to sectioning error layer).
D11 to 14. remainder of common bile duct longitudinally sectioned
D15/16. duodenum and pancreas adjacent to common bile duct
D17. stomach and pancreas including pancreatic duct
D18. two sections of duodenum including transition from tan to dark brown mucosa
D19. two possible lymph nodes.

The pancreatic body margin is inked blue and measures 3.5 x 1.5 cm. The firm area within the pancreas comes within less than 0.1 cm to the blue inked margin.

- D20/21. perpendicular sections through body margin including pancreatic duct
D22. four possible lymph nodes

Frozen Section Diagnosis

C. Bile Duct Margin:

- Mild inflammation.
- Negative for atypia or malignancy.

Reported by:

Accession Number
Encounter Number
Patient Location

Source: NCI Genomic Data Commons file 69248eb3-d568-4b4d-b8f1-b78272c3aaca (TCGA-IB-AAUU.92A95964-6584-4BB6-BBC1-B6B2F2A89B05.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).